Somatic mutation profile of tumor specimen C3L-00446-01 (aliquot CPT0129030006) from CPTAC case C3L-00446, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 73.0 years (26,653 days).
Specimen C3L-00446-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 61fd1d81-6bed-4f30-8688-c9b28e5bd118.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00446-31 (Blood Derived Normal), aliquot CPT0129890002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c9d4cef-7a03-4288-875c-a5a601c7a5df

The open-access MAF lists 1,148 somatic variants for this specimen: 770 protein-altering or splice-affecting, 241 silent, 137 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 677, Silent 241, Intron 68, Nonsense Mutation 52, RNA 25, Splice Site 23, 5'UTR 18, 5'Flank 13, 3'UTR 12, Frame Shift Del 7, Splice Region 4, Frame Shift Ins 4.

Variants (750 of 1,148; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTN2 | c.2578C>T p.Q860* | Nonsense Mutation (SNP) | VAF 68/459 reads (15%) | catalogued as rs763078071; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 52/238 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- SLC26A4 | c.946G>T p.G316* | Nonsense Mutation (SNP) | VAF 44/316 reads (14%) | catalogued as rs1554357231, CM057510; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.839G>T p.R280I | Missense Mutation (SNP) | VAF 118/697 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AC097636.1 | c.152G>A p.R51K | Missense Mutation (SNP) | VAF 13/188 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as rs1440755049, COSV101469680; called by muse, mutect2
- ACOT7 | c.540G>T p.V180= (on ENST00000377855 / NM_181864.3; = p.V170= on NM_007274.4) | Splice Region (SNP) | VAF 29/251 reads (12%) | catalogued as COSV100830154; called by muse, mutect2, varscan2
- ADAM20 | c.1523G>A p.C508Y | Missense Mutation (SNP) | VAF 42/238 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748224006; called by muse, mutect2, varscan2
- ADAMTS13 | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 106/727 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs281875288, CM090520, COSV100746924; ClinVar: not provided; called by muse, mutect2, varscan2
- ADAMTS20 | c.2309G>A p.G770E | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV67141373; called by muse, mutect2
- ADAMTS9 | c.3596G>T p.G1199V | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55791455; called by muse, mutect2
- ADCY5 | c.1258C>T p.H420Y | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.629); catalogued as rs1477933449; called by muse, mutect2
- ADCY8 | c.3527C>A p.P1176H | Missense Mutation (SNP) | VAF 35/216 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.706); catalogued as COSV53902311, COSV53931446; called by muse, mutect2, varscan2
- ADGRV1 | c.15289G>T p.V5097L | Missense Mutation (SNP) | VAF 44/255 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs1359099427; called by muse, mutect2, varscan2
- ADIG | c.178G>T p.G60C | Missense Mutation (SNP) | VAF 54/371 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as rs1351763241; called by muse, mutect2, varscan2
- AR | c.1364G>A p.G455D | Missense Mutation (SNP) | VAF 60/209 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.969); catalogued as COSV65957705; called by mutect2, varscan2
- ASB18 | c.1057C>T p.L353F | Missense Mutation (SNP) | VAF 40/578 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); catalogued as rs1466747619; called by muse, mutect2
- ASCL1 | c.41A>G p.Q14R | Missense Mutation (SNP) | VAF 32/271 reads (12%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.019); catalogued as COSV57152565; called by muse, mutect2, varscan2
- ASTN2 | c.997G>T p.V333L | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as COSV100531391; called by muse, mutect2, varscan2
- ATF6 | c.201G>A p.M67I | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as COSV63409254; called by muse, mutect2
- ATP13A2 | c.3473G>T p.R1158L | Missense Mutation (SNP) | VAF 47/704 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs544885605; called by muse, mutect2
- AVPR1B | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 43/289 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.127); catalogued as rs1287040763, COSV100899374; called by muse, mutect2, varscan2
- BRINP3 | c.1961C>T p.P654L | Missense Mutation (SNP) | VAF 38/337 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV66528591; called by muse, mutect2, varscan2
- BSND | c.507C>A p.D169E | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.466); catalogued as COSV100987669; called by muse, mutect2, varscan2
- C5orf52 | c.328G>T p.A110S | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.51); catalogued as COSV69626595; called by muse, mutect2
- CACNA1C | c.295C>A p.R99S | Missense Mutation (SNP) | VAF 124/445 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59694699; called by muse, mutect2, varscan2
- CAPN11 | c.1328C>A p.T443N | Missense Mutation (SNP) | VAF 29/232 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs777539515; called by muse, mutect2, varscan2
- CASQ2 | c.479G>T p.R160L | Missense Mutation (SNP) | VAF 29/396 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.793); catalogued as rs372283956, COSV54772010, COSV99797783; called by muse, mutect2
- CCDC39 | c.2626C>A p.R876S | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV56480906; called by muse, mutect2, varscan2
- CCER1 | c.670G>T p.E224* | Nonsense Mutation (SNP) | VAF 16/216 reads (7%) | catalogued as rs574692889, COSV100727162, COSV62646194, COSV62646946; called by muse, mutect2
- CD1D | c.136G>T p.G46C | Missense Mutation (SNP) | VAF 59/712 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.636); catalogued as rs1412947803, COSV63808444; called by muse, mutect2
- CD5 | c.193G>A p.G65S | Missense Mutation (SNP) | VAF 51/398 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.024); catalogued as rs1240913459; called by muse, mutect2, varscan2
- CDH2 | c.2674C>T p.P892S | Missense Mutation (SNP) | VAF 56/420 reads (13%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); catalogued as rs1328130862; called by muse, varscan2
- CDH9 | c.479C>T p.T160I | Missense Mutation (SNP) | VAF 10/137 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV50317169; called by muse, mutect2
- CHAT | c.1274C>A p.S425Y | Missense Mutation (SNP) | VAF 56/327 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1448631903, COSV100340197; called by muse, mutect2, varscan2
- CHRNA6 | c.919C>G p.L307V | Missense Mutation (SNP) | VAF 45/310 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as rs201852908; called by muse, mutect2, varscan2
- CHRNA6 | c.274G>T p.D92Y | Missense Mutation (SNP) | VAF 29/183 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs924570495; called by muse, mutect2, varscan2
- CILP2 | c.3455G>T p.G1152V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as rs1367517065; called by muse, mutect2
- CLDN6 | c.577C>A p.P193T | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV58510316; called by muse, mutect2
- CLIP4 | c.1439G>C p.R480P | Missense Mutation (SNP) | VAF 34/426 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.052); catalogued as rs781563201; called by muse, mutect2
- CLSTN2 | c.2542G>T p.V848L | Missense Mutation (SNP) | VAF 51/295 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV71722890; called by muse, mutect2, varscan2
- CLVS2 | c.565G>T p.D189Y | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.528); catalogued as COSV51559200; called by muse, mutect2, varscan2
- COL11A1 | c.4351G>T p.E1451* | Nonsense Mutation (SNP) | VAF 14/212 reads (7%) | catalogued as COSV62183222; called by muse, mutect2
- COL1A2 | c.1006G>T p.A336S | Missense Mutation (SNP) | VAF 98/913 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs757569298; called by muse, mutect2, varscan2
- COL4A3 | c.3683G>T p.G1228V | Missense Mutation (SNP) | VAF 30/617 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1183958961; called by muse, mutect2
- COL4A4 | c.3763C>T p.P1255S | Missense Mutation (SNP) | VAF 42/598 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.093); catalogued as COSV61636721; called by muse, mutect2
- COL5A3 | c.1913G>A p.G638D | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs746054503; called by muse, mutect2, varscan2
- COL9A1 | c.1723G>T p.V575L | Missense Mutation (SNP) | VAF 16/193 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57885013; called by muse, mutect2
- CPA5 | c.1073A>T p.Y358F | Missense Mutation (SNP) | VAF 70/317 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV62570053; called by muse, mutect2, varscan2
- CR1 | c.5861C>A p.A1954E | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as rs781466248, COSV65456009; called by muse, mutect2, varscan2
- CRABP2 | c.70G>T p.G24W | Missense Mutation (SNP) | VAF 48/173 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs774132730; called by muse, mutect2, varscan2
- CSMD3 | c.761G>T p.S254I | Missense Mutation (SNP) | VAF 14/209 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV52138778; called by muse, mutect2
- CTNND2 | c.1210G>T p.G404W | Missense Mutation (SNP) | VAF 68/517 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV58870475; called by muse, mutect2, varscan2
- CUBN | c.10612G>T p.E3538* | Nonsense Mutation (SNP) | VAF 42/351 reads (12%) | catalogued as rs756614749; called by muse, mutect2, varscan2
- CUBN | c.4753C>T p.Q1585* | Nonsense Mutation (SNP) | VAF 86/558 reads (15%) | catalogued as rs145061533, COSV64721637; called by muse, mutect2, varscan2
- DCAF4L2 | c.860C>A p.S287* | Nonsense Mutation (SNP) | VAF 26/269 reads (10%) | catalogued as rs202221876; called by muse, mutect2
- DLGAP2 | c.982C>A p.P328T | Missense Mutation (SNP) | VAF 25/229 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as COSV70096785, COSV70097155; called by muse, mutect2
- DLGAP2 | c.983C>A p.P328H | Missense Mutation (SNP) | VAF 25/222 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.678); catalogued as COSV70096078; called by muse, mutect2
- DMBX1 | c.343G>T p.V115L | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.928); catalogued as COSV100760956; called by muse, mutect2, varscan2
- DOCK2 | c.434A>T p.K145M | Missense Mutation (SNP) | VAF 36/236 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99916547; called by muse, mutect2, varscan2
- DYSF | c.4105T>A p.C1369S | Missense Mutation (SNP) | VAF 69/404 reads (17%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.968); catalogued as COSV99244290; called by muse, mutect2, varscan2
- EFHB | c.131G>T p.G44V | Missense Mutation (SNP) | VAF 36/472 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.07); catalogued as COSV55547068; called by muse, mutect2
- EPHA3 | c.375G>T p.M125I | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV60694251; called by muse, mutect2, varscan2
- EPHA6 | c.2405G>T p.G802V (on ENST00000389672 / NM_001080448.3; = p.G194V on NM_173655.4) | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.964); catalogued as COSV67600693; called by muse, mutect2
- ERICH3 | c.4536T>G p.H1512Q | Missense Mutation (SNP) | VAF 27/174 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV58599746; called by muse, mutect2, varscan2
- ESYT2 | c.319G>T p.V107L (on ENST00000613624; = p.V31L on NM_020728.3) | Missense Mutation (SNP) | VAF 71/364 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.022); catalogued as rs1218752380; called by muse, mutect2, varscan2
- EYS | c.4190C>A p.S1397Y | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as rs892657143, COSV58196894; called by muse, mutect2, varscan2
- FAM124A | c.263G>T p.R88L (on ENST00000322475 / NM_001242312.2; = p.R124L on NM_145019.4) | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.754); catalogued as COSV54478842; called by muse, mutect2
- FAT2 | c.9772G>A p.G3258R | Missense Mutation (SNP) | VAF 39/646 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99943287; called by muse, mutect2
- FBN1 | c.6872-1G>T p.X2291_splice | Splice Site (SNP) | VAF 34/443 reads (8%) | catalogued as CS161893, COSV57318634; called by muse, mutect2
- FBXO31 | c.1283G>T p.G428V | Missense Mutation (SNP) | VAF 81/473 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV100291390; called by muse, mutect2, varscan2
- FBXO44 | c.31G>T p.E11* | Nonsense Mutation (SNP) | VAF 28/330 reads (8%) | catalogued as COSV52354981; called by muse, mutect2
- FCN1 | c.719T>A p.V240D | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as rs750248344; called by muse, mutect2, varscan2
- FMN1 | c.4216-2A>G p.X1406_splice (on ENST00000616417 / NM_001277313.2; = p.X1183_splice on NM_001103184.4) | Splice Site (SNP) | VAF 24/190 reads (13%) | catalogued as rs752508064; called by muse, mutect2, varscan2
- FOXG1 | c.703C>A p.L235I | Missense Mutation (SNP) | VAF 131/586 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57397834; called by muse, mutect2, varscan2
- FTMT | c.104G>A p.G35E | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.027); catalogued as rs370169492; called by muse, mutect2
- GAB1 | c.271G>T p.D91Y | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53759256; called by muse, mutect2
- GHRL | c.65T>C p.M22T | Missense Mutation (SNP) | VAF 20/340 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as rs1393283820; called by muse, mutect2
- GOLGA8S | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 20/624 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.045); catalogued as rs1443103603; called by muse, mutect2
- GZMB | c.250C>A p.P84T | Missense Mutation (SNP) | VAF 70/330 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs769013244; called by muse, mutect2, varscan2
- HBG2 | c.194G>T p.G65V | Missense Mutation (SNP) | VAF 54/1210 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM145510; called by muse, mutect2
- HDGFL1 | c.86T>G p.I29R | Missense Mutation (SNP) | VAF 35/438 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV57751644; called by muse, mutect2
- HOXA2 | c.1057G>C p.D353H | Missense Mutation (SNP) | VAF 90/488 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.08); catalogued as COSV56066135; called by muse, mutect2, varscan2
- HOXB1 | c.79G>C p.A27P | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.457); catalogued as rs1305173448; called by muse, mutect2, varscan2
- HTR5A | c.250G>A p.V84I | Missense Mutation (SNP) | VAF 39/367 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as rs866283043, COSV55280411; called by muse, mutect2, varscan2
- IFNL2 | c.463C>A p.L155I | Missense Mutation (SNP) | VAF 53/303 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs776193226; called by muse, mutect2, varscan2
- IGHV2-70 | c.109C>A p.L37I | Missense Mutation (SNP) | VAF 57/364 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368945949; called by muse, mutect2, varscan2
- IRF2 | c.364+1G>A p.X122_splice | Splice Site (SNP) | VAF 28/283 reads (10%) | catalogued as COSV66929197; called by muse, mutect2
- ITGAX | c.713G>T p.R238L | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV51645561; called by muse, mutect2
- JAKMIP2 | c.800G>T p.G267V | Missense Mutation (SNP) | VAF 114/396 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV54598703; called by muse, mutect2, varscan2
- KAZN | c.1027C>T p.R343W | Missense Mutation (SNP) | VAF 21/260 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs748019374, COSV63207069; called by muse, mutect2
- KCNA1 | c.862C>A p.L288M | Missense Mutation (SNP) | VAF 130/434 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV101230406; called by muse, mutect2, varscan2
- KIAA1522 | c.716G>C p.R239P (on ENST00000373480 / NM_001198972.2; = p.R298P on NM_020888.3) | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.955); catalogued as COSV53866043; called by muse, mutect2, varscan2
- KIAA2026 | c.5974G>T p.V1992F | Missense Mutation (SNP) | VAF 24/207 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.178); catalogued as rs1481698038; called by muse, mutect2, varscan2
- KIF2B | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV99275478; called by muse, varscan2
- KIFAP3 | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); catalogued as rs1261968338; called by muse, mutect2
- KRTAP21-1 | c.221G>A p.R74K | Missense Mutation (SNP) | VAF 77/501 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.083); catalogued as rs1428012505, COSV58645893; called by muse, mutect2, varscan2
- LAMB4 | c.4953G>T p.Q1651H | Missense Mutation (SNP) | VAF 70/293 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.275); catalogued as COSV52721541; called by muse, mutect2, varscan2
- LARP1B | c.1116G>A p.W372* | Nonsense Mutation (SNP) | VAF 27/163 reads (17%) | catalogued as rs1271338014; called by muse, mutect2, varscan2
- LCN8 | c.118G>T p.G40C (on ENST00000612714 / NM_001345934.1; = p.G17C on NM_178469.3) | Missense Mutation (SNP) | VAF 31/412 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs370373572; called by muse, mutect2
- LILRB4 | c.1144G>C p.G382R (on ENST00000391733 / NM_001278428.3; = p.G381R on NM_001278426.3) | Missense Mutation (SNP) | VAF 139/580 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs1412614228; called by muse, mutect2, varscan2
- LIN54 | c.385G>A p.G129S | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.009); catalogued as rs1469948749; called by muse, mutect2
- LRFN5 | c.1558A>T p.M520L | Missense Mutation (SNP) | VAF 61/272 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs750924222; called by muse, mutect2, varscan2
- LRP1 | c.10380C>A p.C3460* | Nonsense Mutation (SNP) | VAF 9/103 reads (9%) | catalogued as rs1555187607; called by muse, mutect2
- LRP1B | c.1496G>T p.R499L | Missense Mutation (SNP) | VAF 24/259 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV67242727; called by muse, mutect2
- LRRC52 | c.412C>A p.L138M | Missense Mutation (SNP) | VAF 110/662 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs373088117, COSV99674049; called by muse, mutect2, varscan2
- LRRC55 | c.89T>A p.M30K | Missense Mutation (SNP) | VAF 48/259 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs757021301; called by muse, mutect2, varscan2
- LRRC7 | c.2263G>C p.V755L (on ENST00000651989 / NM_001370785.2; = p.V722L on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV50465286; called by muse, mutect2
- LRRTM1 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 23/433 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0.084); catalogued as rs570950310, COSV54446546; called by muse, mutect2
- LTBP2 | c.1822T>A p.C608S | Missense Mutation (SNP) | VAF 92/521 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1158191941; called by muse, mutect2, varscan2
- MAGEB18 | c.441G>T p.E147D | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV100305638; called by muse, mutect2, varscan2
- MAP2K2 | c.395G>T p.G132V | Missense Mutation (SNP) | VAF 19/220 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM071856, CM112525; called by muse, mutect2
- MAP3K4 | c.784G>T p.E262* | Nonsense Mutation (SNP) | VAF 28/200 reads (14%) | catalogued as COSV62331972; called by muse, mutect2, varscan2
- MARF1 | c.2248G>T p.A750S | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs370385036; called by muse, mutect2, varscan2
- MIA2 | c.506A>T p.Y169F | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs1464924855; called by muse, mutect2, varscan2
- MORC1 | c.2632G>C p.E878Q | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV51714451; called by muse, mutect2, varscan2
- MRPS17 | c.55G>T p.G19W | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.363); catalogued as COSV53392371; called by muse, mutect2
- MRPS30 | c.1181G>T p.W394L | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50181502; called by muse, varscan2
- MS4A1 | c.433C>A p.H145N | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.045); catalogued as COSV100619407; called by muse, mutect2, varscan2
- MS4A7 | c.227A>T p.N76I | Missense Mutation (SNP) | VAF 25/215 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.211); catalogued as COSV55730937; called by muse, mutect2, varscan2
- MUC7 | c.-15G>A | Splice Region (SNP) | VAF 8/55 reads (15%) | catalogued as rs867134981; called by muse, mutect2, varscan2
- MYH13 | c.485C>A p.A162D | Missense Mutation (SNP) | VAF 42/342 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99355310; called by muse, mutect2, varscan2
- MYO15A | c.235G>T p.V79L | Missense Mutation (SNP) | VAF 112/638 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.406); catalogued as rs201749134, COSV99231547; called by muse, mutect2, varscan2
- NCKIPSD | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 38/484 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1347348988; called by muse, mutect2
- NID2 | c.1319C>A p.P440H | Missense Mutation (SNP) | VAF 81/386 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.535); catalogued as COSV99356522; called by muse, mutect2, varscan2
- NKAPL | c.1063C>T p.R355C | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as COSV100642525; called by muse, mutect2, varscan2
- NKX2-4 | c.577C>A p.R193S | Missense Mutation (SNP) | VAF 104/420 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61085291; called by muse, mutect2, varscan2
- NPAP1 | c.1307C>A p.P436H | Missense Mutation (SNP) | VAF 10/143 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV61508778; called by muse, mutect2
- NPAP1 | c.2989C>A p.L997M | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.793); catalogued as COSV61508133; called by muse, mutect2
- NRK | c.4252G>T p.G1418C | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99687839; called by muse, mutect2, varscan2
- NUP155 | c.3232A>G p.M1078V (on ENST00000231498 / NM_153485.3; = p.M1019V on NM_004298.4) | Missense Mutation (SNP) | VAF 38/229 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as rs760884792, COSV51533655; called by muse, mutect2, varscan2
- OR13C2 | c.450C>G p.I150M | Missense Mutation (SNP) | VAF 36/255 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV73377701; called by muse, mutect2, varscan2
- OR13F1 | c.710C>A p.A237D | Missense Mutation (SNP) | VAF 15/307 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1554731063; called by muse, mutect2
- OR2L2 | c.474C>A p.H158Q | Missense Mutation (SNP) | VAF 38/268 reads (14%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.838); catalogued as COSV100823279; called by muse, mutect2, varscan2
- OR4A47 | c.457C>A p.H153N | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs774432145, COSV101487108; called by muse, mutect2
- OR4C16 | c.283T>C p.C95R | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58942835; called by muse, mutect2, varscan2
- OR4C46 | c.604G>T p.G202* | Nonsense Mutation (SNP) | VAF 20/394 reads (5%) | catalogued as COSV100060902; called by muse, mutect2
- OR4S2 | c.900G>T p.W300C | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.786); catalogued as COSV56747089; called by muse, varscan2
- OR52J3 | c.233C>A p.T78N | Missense Mutation (SNP) | VAF 32/487 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV100984871; called by muse, mutect2
- OR8K1 | c.188C>T p.T63I | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.33); catalogued as rs560184936, COSV54403307; called by muse, mutect2
- OR8U1 | c.763C>T p.L255F | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs1380496651; called by muse, varscan2
- OR9A2 | c.193C>T p.L65F | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.953); catalogued as rs1391467649; called by muse, mutect2, varscan2
- ORC5 | c.1246A>G p.I416V | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs1562802867; called by muse, mutect2, varscan2
- OTOF | c.2060C>T p.S687F | Missense Mutation (SNP) | VAF 27/232 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as rs766858052; called by muse, mutect2, varscan2
- P4HTM | c.1456C>G p.Q486E (on ENST00000383729 / NM_177939.3; = p.Q547E on NM_177938.2) | Missense Mutation (SNP) | VAF 24/329 reads (7%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.121); catalogued as COSV59086875; called by muse, mutect2
- PCDHA7 | c.1478C>A p.S493* | Nonsense Mutation (SNP) | VAF 140/820 reads (17%) | catalogued as COSV65344814; called by muse, varscan2
- PCDHA7 | c.1622G>T p.G541V | Missense Mutation (SNP) | VAF 188/1039 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65346939; called by muse, varscan2
- PCDHB3 | c.1498C>G p.L500V | Missense Mutation (SNP) | VAF 264/930 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.767); catalogued as rs782030800; called by muse, varscan2
- PDCD11 | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 39/275 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV63934778; called by muse, mutect2, varscan2
- PDGFRB | c.2132C>A p.P711H | Missense Mutation (SNP) | VAF 47/436 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.626); catalogued as COSV99940637; called by muse, mutect2, varscan2
- PEG3 | c.1256G>A p.G419D | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as rs1358248416; called by muse, mutect2, varscan2
- PGS1 | c.1366G>T p.E456* | Nonsense Mutation (SNP) | VAF 13/95 reads (14%) | catalogued as COSV53148818; called by muse, mutect2, varscan2
- PHF20 | c.1412A>G p.Y471C | Missense Mutation (SNP) | VAF 42/294 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1307109193; called by muse, mutect2, varscan2
- PIK3C2B | c.2974C>T p.R992C | Missense Mutation (SNP) | VAF 45/392 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs1284556272, COSV65814672; called by muse, mutect2, varscan2
- PKM | c.502G>T p.V168L | Missense Mutation (SNP) | VAF 44/511 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as rs772116077; called by muse, mutect2
- PLB1 | c.1876G>T p.V626F | Missense Mutation (SNP) | VAF 38/335 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59828021; called by muse, mutect2, varscan2
- PLB1 | c.2203C>A p.P735T | Missense Mutation (SNP) | VAF 22/324 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59823084; called by muse, mutect2
- PLD1 | c.2290G>A p.A764T | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs987473173; called by muse, mutect2, varscan2
- PLEC | c.2641G>A p.A881T (on ENST00000322810 / NM_201380.4; = p.A771T on NM_000445.5) | Missense Mutation (SNP) | VAF 56/718 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1554715506; called by muse, mutect2
- PLEKHB2 | c.491C>A p.T164K | Missense Mutation (SNP) | VAF 34/322 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs1478908696, COSV100389047; called by muse, mutect2, varscan2
- PLG | c.850C>A p.R284S | Missense Mutation (SNP) | VAF 48/391 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV51987988; called by muse, mutect2, varscan2
- PLXNB3 | c.4408G>A p.A1470T | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1310280930; called by muse, mutect2, varscan2
- POTEH | c.1392G>T p.M464I | Missense Mutation (SNP) | VAF 81/1634 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs1319166381; called by muse, mutect2
- PPP4R1 | c.502G>T p.D168Y (on ENST00000400556 / NM_001042388.3; = p.D151Y on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/292 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV104374195; called by muse, varscan2
- PSG7 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.749); catalogued as rs887148891, COSV101343172; called by muse, mutect2, varscan2
- PTPRT | c.3255-1G>T p.X1085_splice | Splice Site (SNP) | VAF 18/115 reads (16%) | catalogued as COSV99049543; called by muse, mutect2
- PTPRT | c.1973T>C p.L658P | Missense Mutation (SNP) | VAF 46/606 reads (8%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.984); catalogued as COSV61981884; called by muse, mutect2
- QDPR | c.23G>T p.G8V | Missense Mutation (SNP) | VAF 30/350 reads (9%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.131); catalogued as rs1311794369; called by muse, mutect2
- RAG2 | c.1483C>G p.L495V | Missense Mutation (SNP) | VAF 34/375 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57556728; called by muse, mutect2
- RASAL1 | c.2223-1G>T p.X741_splice | Splice Site (SNP) | VAF 34/259 reads (13%) | catalogued as COSV99922161; called by muse, mutect2, varscan2
- RBM15 | c.1526A>G p.H509R | Missense Mutation (SNP) | VAF 36/289 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.375); catalogued as rs778454025; called by muse, mutect2, varscan2
- RBM6 | c.782A>C p.H261P | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV99804283; called by muse, mutect2
- RGPD4 | c.4982C>A p.S1661Y | Missense Mutation (SNP) | VAF 69/596 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.099); catalogued as COSV100736561; called by muse, mutect2, varscan2
- RILPL1 | c.632G>C p.R211P | Missense Mutation (SNP) | VAF 84/518 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV100525980; called by muse, mutect2, varscan2
- RYR1 | c.9668C>T p.S3223F | Missense Mutation (SNP) | VAF 24/344 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs1275704430; called by muse, mutect2
- RYR2 | c.4603C>G p.P1535A | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV100769615, COSV63660633; called by muse, mutect2, varscan2
- SALL3 | c.3323G>T p.R1108L | Missense Mutation (SNP) | VAF 56/366 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV73306425; called by muse, mutect2, varscan2
- SARDH | c.1041C>A p.F347L | Missense Mutation (SNP) | VAF 57/278 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100897852; called by muse, mutect2, varscan2
- SCRN1 | c.1028G>T p.R343L | Missense Mutation (SNP) | VAF 37/334 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV54131017; called by muse, mutect2, varscan2
- SCRN2 | c.635C>G p.A212G | Missense Mutation (SNP) | VAF 51/398 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs757251902; called by muse, mutect2, varscan2
- SEMA3D | c.712C>G p.L238V | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as COSV52395308; called by muse, mutect2, varscan2
- SEPTIN6 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 75/209 reads (36%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.99); catalogued as rs746468087, COSV100595579; called by muse, mutect2, varscan2
- SI | c.4681G>A p.A1561T | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.038); catalogued as rs768264563, COSV100014528; called by muse, varscan2
- SIGLEC12 | c.811C>T p.L271= (on ENST00000291707 / NM_053003.4; = p.L153= on NM_033329.2) | Splice Region (SNP) | VAF 51/225 reads (23%) | catalogued as COSV99389476; called by muse, mutect2, varscan2
- SLC22A10 | c.1494G>T p.W498C | Missense Mutation (SNP) | VAF 53/371 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60421277; called by muse, mutect2, varscan2
- SLC39A4 | c.1412C>T p.A471V (on ENST00000301305 / NM_001374839.1; = p.A446V on NM_017767.3) | Missense Mutation (SNP) | VAF 36/534 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.477); catalogued as rs373461634; called by muse, mutect2
- SLC46A3 | c.306C>G p.F102L | Missense Mutation (SNP) | VAF 58/266 reads (22%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV57182961; called by muse, mutect2, varscan2
- SLC4A1 | c.1550C>A p.S517Y | Missense Mutation (SNP) | VAF 63/459 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1391855595; called by muse, mutect2, varscan2
- SLC8A3 | c.1165G>T p.D389Y | Missense Mutation (SNP) | VAF 56/262 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.742); catalogued as COSV100775835; called by muse, mutect2, varscan2
- SLC9A9 | c.1380G>C p.M460I | Missense Mutation (SNP) | VAF 29/274 reads (11%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.968); catalogued as COSV57221242; called by muse, mutect2, varscan2
- SLFN11 | c.1198G>T p.V400F | Missense Mutation (SNP) | VAF 23/188 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV57700904; called by muse, mutect2, varscan2
- SLIT2 | c.59T>A p.L20Q | Missense Mutation (SNP) | VAF 19/243 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs1249392010; called by muse, mutect2
- SNRNP200 | c.5271G>T p.W1757C | Missense Mutation (SNP) | VAF 62/470 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as COSV60493328; called by muse, mutect2, varscan2
- SOCS2 | c.526G>T p.G176C | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.496); catalogued as COSV61392291; called by muse, mutect2
- SOCS4 | c.389A>G p.D130G | Missense Mutation (SNP) | VAF 50/171 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs200506527; called by muse, mutect2, varscan2
- SPOCK3 | c.1145T>C p.I382T | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1201770492; called by muse, mutect2, varscan2
- STK11IP | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 66/438 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.053); catalogued as rs760028020; called by muse, mutect2, varscan2
- STYXL2 | c.2474G>T p.S825I | Missense Mutation (SNP) | VAF 34/279 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1558028671; called by muse, mutect2, varscan2
- SYNDIG1L | c.488G>T p.G163V | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100526402, COSV59046911; called by muse, mutect2, varscan2
- TACC2 | c.2555C>T p.P852L | Missense Mutation (SNP) | VAF 31/301 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs758543512, COSV57746181; called by muse, mutect2
- TBXT | c.229G>T p.V77L | Missense Mutation (SNP) | VAF 54/427 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs753229275; called by muse, mutect2, varscan2
- TENM1 | c.7901G>T p.R2634L | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV64437311; called by muse, mutect2, varscan2
- TESMIN | c.295G>T p.G99W | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.815); catalogued as rs1265189059; called by muse, mutect2
- TIMP3 | c.339G>A p.M113I | Missense Mutation (SNP) | VAF 53/422 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs772323070; called by muse, mutect2, varscan2
- TMEM150B | c.148C>A p.P50T | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369382915; called by muse, mutect2, varscan2
- TNR | c.3764T>A p.L1255H | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV54902043; called by muse, mutect2, varscan2
- TPSD1 | c.497G>A p.G166D | Missense Mutation (SNP) | VAF 32/263 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1174043458; called by muse, varscan2
- TRAP1 | c.166G>T p.G56* | Nonsense Mutation (SNP) | VAF 19/148 reads (13%) | catalogued as rs758648066; called by muse, mutect2, varscan2
- TRAPPC9 | c.2705G>T p.R902L | Missense Mutation (SNP) | VAF 81/547 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV66897133; called by muse, mutect2, varscan2
- TRDN | c.1554G>T p.K518N | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.012); catalogued as COSV62128360; called by muse, mutect2
- TRPC5 | c.1421C>G p.P474R | Missense Mutation (SNP) | VAF 47/92 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53289949, COSV53290405; called by muse, mutect2, varscan2
- TTC27 | c.872G>A p.R291K | Missense Mutation (SNP) | VAF 11/137 reads (8%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as rs765531766, COSV58656690; called by muse, mutect2
- TTN | c.53971C>A p.P17991T (on ENST00000591111; = p.P10567T on NM_003319.4) | Missense Mutation (SNP) | VAF 21/264 reads (8%) | PolyPhen benign (0.012); catalogued as COSV60178888; called by muse, mutect2
- TTN | c.5108C>A p.P1703Q (on ENST00000591111; = p.P1657Q on NM_003319.4) | Missense Mutation (SNP) | VAF 24/199 reads (12%) | PolyPhen probably damaging (0.999); catalogued as COSV59994755; called by muse, mutect2, varscan2
- UBE2Z | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as COSV62875306; called by muse, mutect2, varscan2
- UGT2B28 | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs759634172; called by muse, mutect2, varscan2
- UPK1A | c.515C>A p.T172K | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV55879600; called by muse, mutect2, varscan2
- USH2A | c.4555G>C p.G1519R | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56449185; called by muse, mutect2, varscan2
- USP22 | c.35T>C p.M12T | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as rs1302731135; called by muse, mutect2, varscan2
- USP29 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 69/296 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54143722; called by muse, mutect2, varscan2
- WFDC5 | c.311G>A p.G104D | Missense Mutation (SNP) | VAF 44/417 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1267879301, COSV100332154; called by muse, mutect2, varscan2
- WNT16 | c.13G>T p.A5S | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as COSV104382946; called by muse, mutect2, varscan2
- WNT5A | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 24/266 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV52836588; called by muse, mutect2
- XIRP2 | c.5774G>T p.R1925M (on ENST00000628543; = p.R2100M on NM_152381.6) | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs569924701; called by muse, mutect2
- ZAP70 | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 42/282 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1225966715; called by muse, varscan2
- ZCCHC12 | c.371C>G p.S124C | Missense Mutation (SNP) | VAF 104/270 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.789); catalogued as COSV59571159, COSV59571929; called by muse, mutect2, varscan2
- ZFHX4 | c.1498T>A p.F500I | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.178); catalogued as rs1180298790; called by muse, mutect2, varscan2
- ZFHX4 | c.2365G>T p.E789* | Nonsense Mutation (SNP) | VAF 37/233 reads (16%) | catalogued as COSV51458057; called by muse, mutect2, varscan2
- ZFP64 | c.1879G>T p.E627* | Nonsense Mutation (SNP) | VAF 81/526 reads (15%) | catalogued as COSV53796037; called by muse, mutect2, varscan2
- ZNF142 | c.4040C>T p.A1347V (on ENST00000411696 / NM_001379660.1; = p.A1147V on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as rs1257133900; called by muse, mutect2, varscan2
- ZNF382 | c.1126G>T p.G376W | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53087067, COSV99497611; called by muse, mutect2
- ZNF536 | c.2700C>G p.I900M | Missense Mutation (SNP) | VAF 56/286 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as COSV62834521; called by muse, mutect2, varscan2
- ZNF564 | c.686A>G p.E229G | Missense Mutation (SNP) | VAF 35/232 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as rs1259051023; called by muse, mutect2, varscan2
- ZNF578 | c.575C>A p.T192K | Missense Mutation (SNP) | VAF 35/239 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.624); catalogued as rs778511245; called by muse, mutect2, varscan2
- ZNF729 | c.2301G>T p.L767F | Missense Mutation (SNP) | VAF 36/199 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.48); catalogued as COSV62606914; called by muse, mutect2, varscan2
- ZNF780B | c.195G>A p.W65* | Nonsense Mutation (SNP) | VAF 61/313 reads (19%) | catalogued as COSV55465212; called by muse, mutect2, varscan2
- ZNF804B | c.3425C>T p.P1142L | Missense Mutation (SNP) | VAF 24/213 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs11977547; called by muse, mutect2, varscan2
- ZSCAN12 | c.446C>T p.T149M | Missense Mutation (SNP) | VAF 23/214 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1481948770; called by muse, mutect2, varscan2
- ABCA12 | c.6528C>A p.Y2176* (on ENST00000272895 / NM_173076.3; = p.Y1858* on NM_015657.3) | Nonsense Mutation (SNP) | VAF 18/252 reads (7%) | called by muse, mutect2
- ABCA13 | c.4983G>T p.K1661N | Missense Mutation (SNP) | VAF 38/400 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.117); called by muse, mutect2
- ABCA8 | c.1354G>T p.A452S | Missense Mutation (SNP) | VAF 15/192 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.011); called by muse, mutect2
- ABCB6 | c.2415G>T p.R805S | Missense Mutation (SNP) | VAF 53/302 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ABCC12 | c.3077C>A p.A1026E | Missense Mutation (SNP) | VAF 46/264 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ABHD16B | c.1399T>A p.W467R | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ABLIM3 | c.1853A>G p.Y618C | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- AC005324.2 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.982); called by muse, mutect2
- ACADSB | c.1183A>T p.T395S | Missense Mutation (SNP) | VAF 45/356 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- ACCSL | c.310G>T p.D104Y | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.254); called by muse, mutect2
- ACP7 | c.134C>A p.S45Y | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- ACRBP | c.482A>G p.E161G | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- ACSS3 | c.398A>G p.Y133C | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ACTN4 | c.358G>T p.A120S | Missense Mutation (SNP) | VAF 53/289 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ACTR5 | c.973G>T p.D325Y | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ADAM18 | c.1316C>A p.S439* | Nonsense Mutation (SNP) | VAF 13/110 reads (12%) | called by muse, mutect2, varscan2
- ADAM30 | c.335A>G p.Y112C | Missense Mutation (SNP) | VAF 32/270 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADCY3 | c.931T>C p.Y311H | Missense Mutation (SNP) | VAF 44/283 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRA1 | c.240G>T p.E80D | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- ADGRA3 | c.2156G>A p.G719E | Missense Mutation (SNP) | VAF 22/366 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ADGRB1 | c.1262G>C p.C421S | Missense Mutation (SNP) | VAF 60/337 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- ADGRL3 | c.340C>G p.P114A (on ENST00000506720 / NM_001322402.2; = p.P46A on NM_015236.6) | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- AFP | c.1807A>T p.T603S | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2
- AJAP1 | c.137C>A p.P46Q | Missense Mutation (SNP) | VAF 24/302 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2
- ALDH1L2 | c.2506T>A p.F836I | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AMPD1 | c.1950G>T p.M650I | Missense Mutation (SNP) | VAF 21/212 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2
- AMPH | c.1313A>C p.E438A | Missense Mutation (SNP) | VAF 30/223 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANAPC7 | c.1669A>T p.S557C | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); called by muse, mutect2
- ANK1 | c.2957T>G p.L986R | Missense Mutation (SNP) | VAF 35/445 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ANKRD33B | c.1300C>A p.P434T | Missense Mutation (SNP) | VAF 37/263 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- ANKRD35 | c.1766C>G p.P589R | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ANKRD36 | c.3146G>C p.G1049A | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.99); called by muse, mutect2
- ANKRD49 | c.191G>T p.R64L | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- APOB | c.11849C>A p.A3950E | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.228); called by muse, mutect2
- AQR | c.2710C>G p.R904G | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- ARHGEF12 | c.873G>T p.R291S | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ARHGEF5 | c.484G>T p.G162* | Nonsense Mutation (SNP) | VAF 95/1518 reads (6%) | called by muse, mutect2
- ASCC3 | c.5965G>T p.G1989C | Missense Mutation (SNP) | VAF 50/311 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP13A2 | c.1719G>C p.M573I | Missense Mutation (SNP) | VAF 27/235 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ATP1B3 | c.218G>T p.R73L | Missense Mutation (SNP) | VAF 20/268 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- ATP1B4 | c.559C>A p.Q187K (on ENST00000218008 / NM_001142447.3; = p.Q183K on NM_012069.5) | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.024); called by muse, mutect2
- ATP6V1G3 | c.45A>T p.E15D | Missense Mutation (SNP) | VAF 40/427 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); called by muse, mutect2
- ATRNL1 | c.3691G>T p.V1231L | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ATXN1L | c.1721del p.G574Efs*12 | Frame Shift Del (DEL) | VAF 37/217 reads (17%) | called by mutect2, pindel, varscan2
- BCORL1 | c.1183A>G p.T395A | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- BMPER | c.662G>T p.C221F | Missense Mutation (SNP) | VAF 45/440 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BMPR1B | c.183C>A p.D61E | Missense Mutation (SNP) | VAF 43/360 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, varscan2
- BMS1 | c.237G>C p.E79D | Missense Mutation (SNP) | VAF 41/251 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- BRI3 | c.12G>T p.K4N | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- C12orf66 | c.655G>T p.A219S | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.868); called by muse, mutect2
- C14orf39 | c.761A>T p.K254I | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- C1QL2 | c.124G>T p.G42W | Missense Mutation (SNP) | VAF 29/215 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- C4orf54 | c.1372G>T p.G458C | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- C7 | c.456G>T p.R152S | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.115); called by muse, varscan2
- C9 | c.1145G>T p.G382V | Missense Mutation (SNP) | VAF 18/243 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- CACNA1A | c.6569C>A p.T2190N | Missense Mutation (SNP) | VAF 70/344 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.009); called by muse, varscan2
- CACNA1E | c.5066A>C p.N1689T | Missense Mutation (SNP) | VAF 30/272 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CALY | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 46/587 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.222); called by muse, mutect2
- CAMK2B | c.1598-6C>A | Splice Region (SNP) | VAF 41/297 reads (14%) | called by muse, mutect2, varscan2
- CANT1 | c.1141G>T p.G381W | Missense Mutation (SNP) | VAF 55/323 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAP1 | c.1273C>A p.L425M | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CAPN15 | c.2857G>T p.A953S | Missense Mutation (SNP) | VAF 46/342 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CAPS | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 45/262 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC102B | c.458A>T p.K153I | Missense Mutation (SNP) | VAF 39/218 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- CCDC168 | c.16478A>G p.K5493R | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.848); called by muse, mutect2
- CCDC8 | c.965G>T p.G322V | Missense Mutation (SNP) | VAF 61/224 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- CCR6 | c.619C>A p.P207T | Missense Mutation (SNP) | VAF 60/335 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CD248 | c.1310G>T p.R437M | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.343); called by muse, mutect2
- CDC42EP4 | c.928C>T p.L310F | Missense Mutation (SNP) | VAF 32/376 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.174); called by muse, mutect2
- CDH2 | c.1901C>A p.A634D | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- CDH6 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 58/328 reads (18%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CDS1 | c.1313A>T p.Q438L | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- CEP250 | c.5536G>A p.A1846T | Missense Mutation (SNP) | VAF 36/283 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- CEP295 | c.1225G>T p.D409Y | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, varscan2
- CFAP100 | c.427G>T p.V143L | Missense Mutation (SNP) | VAF 24/240 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CFAP74 | c.3455A>T p.Q1152L | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- CFHR3 | c.58+1G>T p.X20_splice | Splice Site (SNP) | VAF 38/262 reads (15%) | called by muse, varscan2
- CFTR | c.1149G>T p.L383F | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- CHIT1 | c.1355C>A p.T452K | Missense Mutation (SNP) | VAF 56/332 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CHN1 | c.689T>C p.I230T | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.449); called by muse, varscan2
- CHRNA1 | c.1417G>T p.G473C (on ENST00000261007 / NM_001039523.3; = p.G448C on NM_000079.4) | Missense Mutation (SNP) | VAF 66/494 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CIB4 | c.43G>C p.E15Q | Missense Mutation (SNP) | VAF 50/320 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CLASP2 | c.2132G>T p.S711I | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.09); called by muse, mutect2
- CLEC2L | c.254T>A p.M85K | Missense Mutation (SNP) | VAF 32/306 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2
- CLMN | c.994G>T p.G332W | Missense Mutation (SNP) | VAF 50/269 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CLPTM1L | c.1435G>T p.D479Y | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CLRN2 | c.258C>A p.F86L | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CNTNAP4 | c.1724_1725del p.C575Yfs*12 | Frame Shift Del (DEL) | VAF 42/216 reads (19%) | called by mutect2, pindel, varscan2
- COL15A1 | c.2610G>T p.E870D | Missense Mutation (SNP) | VAF 64/445 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL21A1 | c.2723C>A p.P908H | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COL22A1 | c.2719G>T p.G907C | Missense Mutation (SNP) | VAF 54/352 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL4A6 | c.2495C>A p.A832E | Missense Mutation (SNP) | VAF 56/110 reads (51%) | SIFT tolerated (1); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- COL6A1 | c.1242C>G p.N414K | Missense Mutation (SNP) | VAF 26/374 reads (7%) | SIFT tolerated (0.91); PolyPhen benign (0.321); called by muse, mutect2
- COL6A6 | c.3148C>A p.P1050T | Missense Mutation (SNP) | VAF 75/386 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- COLEC10 | c.719G>A p.S240N | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CPB1 | c.466C>A p.L156I | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- CPNE7 | c.178G>T p.G60C | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- CRB2 | c.2795G>A p.G932D | Missense Mutation (SNP) | VAF 42/501 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CSMD1 | c.5411G>T p.S1804I (on ENST00000520002; = p.S1803I on NM_033225.6) | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CSN2 | c.477G>T p.Q159H | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- CTNND2 | c.2708T>C p.I903T | Missense Mutation (SNP) | VAF 41/356 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- CUBN | c.10257G>T p.K3419N | Missense Mutation (SNP) | VAF 32/245 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- CUEDC1 | c.284G>A p.S95N | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, varscan2
- CUX2 | c.943A>T p.K315* | Nonsense Mutation (SNP) | VAF 28/332 reads (8%) | called by muse, mutect2
- CWC25 | c.881G>T p.R294L | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2
- CXCL12 | c.19G>T p.V7F | Missense Mutation (SNP) | VAF 20/399 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.039); called by muse, mutect2
- CYP4F2 | c.77G>T p.G26V | Missense Mutation (SNP) | VAF 36/277 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- CYP4F2 | c.76G>T p.G26W | Missense Mutation (SNP) | VAF 36/274 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CYTIP | c.784C>A p.Q262K | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2
- DACH2 | c.667G>T p.A223S | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- DBR1 | c.296G>T p.W99L | Missense Mutation (SNP) | VAF 63/285 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- DEF8 | c.508G>A p.A170T (on ENST00000268676 / NM_207514.3; = p.A109T on NM_017702.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DEPDC1 | c.1625G>T p.S542I | Missense Mutation (SNP) | VAF 21/179 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- DGKE | c.1284+1G>T p.X428_splice | Splice Site (SNP) | VAF 8/60 reads (13%) | called by muse, mutect2, varscan2
- DHX29 | c.1991G>T p.R664L | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- DHX9 | c.3524G>T p.R1175M | Missense Mutation (SNP) | VAF 62/426 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- DIDO1 | c.5253G>T p.Q1751H | Missense Mutation (SNP) | VAF 45/234 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- DISC1 | c.176C>A p.P59Q | Missense Mutation (SNP) | VAF 64/332 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- DISP3 | c.2973C>A p.C991* | Nonsense Mutation (SNP) | VAF 23/274 reads (8%) | called by muse, mutect2
- DLGAP4 | c.1018G>T p.E340* | Nonsense Mutation (SNP) | VAF 33/207 reads (16%) | called by muse, mutect2, varscan2
- DNAH10 | c.7408T>C p.W2470R (on ENST00000409039; = p.W2409R on NM_207437.3) | Missense Mutation (SNP) | VAF 14/211 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNAH14 | c.1124G>T p.R375M (on ENST00000445597; = p.R356M on NM_001145154.3) | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- DNAJC25 | c.383A>T p.E128V | Missense Mutation (SNP) | VAF 39/219 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNPEP | c.466A>G p.T156A | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- DOCK3 | c.4823T>G p.M1608R | Missense Mutation (SNP) | VAF 15/307 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- DOK3 | c.626G>T p.R209L | Missense Mutation (SNP) | VAF 58/522 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DRC1 | c.2031G>C p.W677C | Missense Mutation (SNP) | VAF 26/273 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DUSP15 | c.441G>T p.R147S | Missense Mutation (SNP) | VAF 34/222 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- DYNC2H1 | c.8060T>A p.L2687Q | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); called by muse, varscan2
- DZIP1L | c.1370C>T p.P457L | Missense Mutation (SNP) | VAF 24/248 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2
- DZIP1L | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 65/437 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- EBAG9 | c.322-1G>T p.X108_splice | Splice Site (SNP) | VAF 7/58 reads (12%) | called by muse, mutect2, varscan2
- ECHDC2 | c.436G>T p.A146S | Missense Mutation (SNP) | VAF 23/418 reads (6%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.999); called by muse, mutect2
- ECPAS | c.3937G>C p.A1313P | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- EDARADD | c.241G>C p.D81H (on ENST00000334232 / NM_145861.4; = p.D71H on NM_080738.4) | Missense Mutation (SNP) | VAF 47/283 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- EEF1A2 | c.508A>T p.I170F | Missense Mutation (SNP) | VAF 42/532 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- EEF1AKMT1 | c.376T>A p.L126I | Missense Mutation (SNP) | VAF 42/176 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- EGFLAM | c.2591T>A p.V864E (on ENST00000354891 / NM_001205301.2; = p.V856E on NM_152403.4) | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- EHD3 | c.1258G>T p.G420C | Missense Mutation (SNP) | VAF 51/251 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- EIF2S3 | c.463G>T p.A155S | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- EMILIN2 | c.460C>A p.P154T | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- ENPEP | c.1510-1G>A p.X504_splice | Splice Site (SNP) | VAF 6/53 reads (11%) | called by muse, mutect2, varscan2
- EPB41L5 | c.804G>C p.W268C | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- EPM2A | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 45/293 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- ERVV-1 | c.798del p.F267Lfs*7 | Frame Shift Del (DEL) | VAF 108/778 reads (14%) | called by mutect2, varscan2
- ESYT3 | c.784C>A p.P262T | Missense Mutation (SNP) | VAF 63/333 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAM135B | c.1870C>G p.Q624E | Missense Mutation (SNP) | VAF 30/268 reads (11%) | SIFT tolerated (0.76); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- FAM171A1 | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 51/311 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.054); called by muse, varscan2
- FAM189A1 | c.739C>A p.P247T | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- FARSA | c.380G>T p.R127L | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- FAT3 | c.12335C>T p.S4112F | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- FAT4 | c.3378T>A p.D1126E | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FBN2 | c.2086G>A p.V696M | Missense Mutation (SNP) | VAF 45/334 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- FBN3 | c.6128A>G p.K2043R | Missense Mutation (SNP) | VAF 39/298 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- FBXL7 | c.76A>G p.S26G | Missense Mutation (SNP) | VAF 30/340 reads (9%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.899); called by muse, mutect2
- FBXO38 | c.1241A>T p.H414L | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.453); called by mutect2, varscan2
- FCGR1A | c.841C>T p.L281F | Missense Mutation (SNP) | VAF 151/1052 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- FCRL2 | c.96C>G p.D32E | Missense Mutation (SNP) | VAF 40/201 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- FCRLB | c.159G>T p.E53D | Missense Mutation (SNP) | VAF 71/522 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- FGF13 | c.717G>C p.M239I | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- FGF18 | c.148A>T p.K50* | Nonsense Mutation (SNP) | VAF 66/288 reads (23%) | called by muse, mutect2, varscan2
- FHAD1 | c.1105G>T p.E369* | Nonsense Mutation (SNP) | VAF 12/218 reads (6%) | called by muse, mutect2
- FIGNL2 | c.1708G>T p.A570S | Missense Mutation (SNP) | VAF 38/382 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.03); called by muse, mutect2
- FKBP6 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 186/877 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- FLNA | c.3383C>T p.P1128L | Missense Mutation (SNP) | VAF 21/325 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); called by muse, mutect2
- FLNC | c.2348A>T p.E783V | Missense Mutation (SNP) | VAF 60/522 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FOXD4L6 | c.809A>T p.Y270F | Missense Mutation (SNP) | VAF 38/239 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.346); called by mutect2, varscan2
- FOXO4 | c.1282G>A p.V428I | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- FOXP2 | c.1501G>A p.A501T | Missense Mutation (SNP) | VAF 22/209 reads (11%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- FREM2 | c.5536G>T p.E1846* | Nonsense Mutation (SNP) | VAF 47/496 reads (9%) | called by muse, mutect2
- FSIP2 | c.4250G>T p.S1417I | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FSTL5 | c.2305G>T p.V769L | Missense Mutation (SNP) | VAF 7/155 reads (5%) | SIFT tolerated (0.99); PolyPhen benign (0.02); called by muse, mutect2
- FXYD7 | c.110T>C p.F37S | Missense Mutation (SNP) | VAF 26/422 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- GABRG2 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 20/249 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GAK | c.3356G>C p.W1119S | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GAL3ST3 | c.521G>T p.R174L | Missense Mutation (SNP) | VAF 61/332 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- GAS2L3 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GATA3 | c.1212C>A p.S404R | Missense Mutation (SNP) | VAF 27/479 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.401); called by muse, mutect2
- GIGYF1 | c.1182del p.A395Rfs*11 | Frame Shift Del (DEL) | VAF 24/168 reads (14%) | called by mutect2, pindel, varscan2
- GIMAP6 | c.86-1G>T p.X29_splice | Splice Site (SNP) | VAF 38/216 reads (18%) | called by muse, mutect2, varscan2
- GLB1 | c.955G>T p.G319W | Missense Mutation (SNP) | VAF 34/368 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GLRA3 | c.305A>G p.N102S | Missense Mutation (SNP) | VAF 18/179 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- GLRA4 | c.686A>G p.D229G | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- GPC3 | c.1591G>A p.D531N | Missense Mutation (SNP) | VAF 94/241 reads (39%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- GPM6A | c.661G>T p.A221S | Missense Mutation (SNP) | VAF 35/330 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- GPR22 | c.776C>A p.T259K | Missense Mutation (SNP) | VAF 23/201 reads (11%) | SIFT tolerated (0.97); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- GPX5 | c.8C>A p.T3K | Missense Mutation (SNP) | VAF 35/201 reads (17%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GRB10 | c.1600T>C p.C534R (on ENST00000398812; = p.C488R on NM_001001549.3) | Missense Mutation (SNP) | VAF 48/296 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- GRB7 | c.1259G>C p.S420T | Missense Mutation (SNP) | VAF 62/498 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRIA1 | c.2408T>A p.L803H | Missense Mutation (SNP) | VAF 37/250 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRID2IP | c.3610G>T p.G1204W | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GRIK2 | c.89A>T p.Q30L | Missense Mutation (SNP) | VAF 23/151 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRM5 | c.300G>T p.W100C | Missense Mutation (SNP) | VAF 32/444 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GRM6 | c.319G>C p.E107Q | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2
- GRM7 | c.1907T>A p.I636N | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- GSTM2 | c.634A>G p.I212V | Missense Mutation (SNP) | VAF 32/227 reads (14%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- H2BC3 | c.277A>T p.R93W | Missense Mutation (SNP) | VAF 42/249 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- HDAC4 | c.2761G>C p.E921Q | Missense Mutation (SNP) | VAF 40/634 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.573); called by muse, mutect2
- HEG1 | c.1402G>T p.D468Y | Missense Mutation (SNP) | VAF 57/248 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- HHIPL2 | c.536A>T p.Y179F | Missense Mutation (SNP) | VAF 90/646 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- HIVEP1 | c.4286T>A p.L1429Q | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HIVEP2 | c.5941A>C p.T1981P | Missense Mutation (SNP) | VAF 36/273 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HIVEP2 | c.787G>T p.G263C | Missense Mutation (SNP) | VAF 41/199 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- HJURP | c.2066A>T p.Q689L | Missense Mutation (SNP) | VAF 55/373 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HK3 | c.181G>C p.A61P | Missense Mutation (SNP) | VAF 11/318 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- HMCN2 | c.13469T>A p.L4490H | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HSPA2 | c.1110G>C p.E370D | Missense Mutation (SNP) | VAF 54/303 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HTR2C | c.617C>A p.T206K | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- IFI6 | c.178G>T p.G60C | Missense Mutation (SNP) | VAF 21/215 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IGKV1-39 | c.47G>A p.W16* | Nonsense Mutation (SNP) | VAF 16/136 reads (12%) | called by mutect2, varscan2
- IGKV2-30 | c.354C>A p.H118Q | Missense Mutation (SNP) | VAF 67/539 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGKV3D-20 | c.284C>A p.T95N | Missense Mutation (SNP) | VAF 56/404 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); called by mutect2, varscan2
- IGKV3D-7 | c.205A>T p.R69W | Missense Mutation (SNP) | VAF 38/816 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- IL12B | c.947G>T p.S316I | Missense Mutation (SNP) | VAF 81/585 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- IL17RA | c.1627C>T p.Q543* | Nonsense Mutation (SNP) | VAF 62/418 reads (15%) | called by muse, mutect2, varscan2
- IL1RL1 | c.7T>C p.F3L | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IL4I1 | c.307G>T p.D103Y | Missense Mutation (SNP) | VAF 25/362 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- INPPL1 | c.1190G>T p.S397I | Missense Mutation (SNP) | VAF 46/284 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- INTU | c.1325C>T p.A442V | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT tolerated (0.96); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ISL1 | c.258C>A p.F86L | Missense Mutation (SNP) | VAF 69/433 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- ISLR2 | c.1790G>T p.S597I | Missense Mutation (SNP) | VAF 34/422 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ITGA1 | c.3082G>T p.A1028S | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- ITIH5 | c.2458C>A p.Q820K | Missense Mutation (SNP) | VAF 46/289 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- JAG2 | c.999C>A p.C333* | Nonsense Mutation (SNP) | VAF 118/615 reads (19%) | called by muse, mutect2, varscan2
- JAK3 | c.83T>G p.V28G | Missense Mutation (SNP) | VAF 34/233 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- JUP | c.1876G>C p.A626P | Missense Mutation (SNP) | VAF 40/224 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- KAT6A | c.1154A>G p.E385G | Missense Mutation (SNP) | VAF 12/193 reads (6%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.979); called by muse, mutect2
- KAT6B | c.3282del p.E1095Kfs*19 | Frame Shift Del (DEL) | VAF 46/388 reads (12%) | called by mutect2, varscan2
- KATNAL1 | c.1390G>T p.A464S | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- KATNIP | c.3161G>C p.R1054P | Missense Mutation (SNP) | VAF 33/236 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNH1 | c.665G>T p.W222L | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNH1 | c.112G>T p.V38L | Missense Mutation (SNP) | VAF 28/206 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- KCNJ1 | c.26T>A p.F9Y | Missense Mutation (SNP) | VAF 54/377 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- KCNK6 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 78/336 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KCP | c.4189G>T p.A1397S (on ENST00000620378; = p.A1521S on NM_001366122.1) | Missense Mutation (SNP) | VAF 105/446 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- KHDRBS3 | c.87A>C p.Q29H | Missense Mutation (SNP) | VAF 34/270 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KIAA2026 | c.5973G>T p.K1991N | Missense Mutation (SNP) | VAF 24/206 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- KIF13B | c.3480-1G>C p.X1160_splice | Splice Site (SNP) | VAF 16/186 reads (9%) | called by muse, mutect2
- KIF21A | c.2703-1G>T p.X901_splice (on ENST00000361418 / NM_001378440.1; = p.X888_splice on NM_017641.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 65/300 reads (22%) | called by muse, mutect2, varscan2
- KIF4B | c.1562A>T p.Q521L | Missense Mutation (SNP) | VAF 37/314 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- KIR2DL3 | c.986A>G p.D329G | Missense Mutation (SNP) | VAF 100/479 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- KL | c.1801C>A p.L601M | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- KLHL11 | c.2039G>A p.W680* | Nonsense Mutation (SNP) | VAF 37/277 reads (13%) | called by muse, mutect2, varscan2
- KLHL14 | c.769G>T p.A257S | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- KLHL30 | c.984C>G p.I328M | Missense Mutation (SNP) | VAF 86/360 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- KLHL4 | c.1052A>T p.Q351L | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLHL9 | c.966_969del p.R323Hfs*7 | Frame Shift Del (DEL) | VAF 70/338 reads (21%) | called by mutect2, pindel, varscan2
- KPTN | c.44G>T p.R15L | Missense Mutation (SNP) | VAF 23/380 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2
- KRT4 | c.835-2A>T p.X279_splice | Splice Site (SNP) | VAF 48/622 reads (8%) | called by muse, mutect2
- LAMB3 | c.189G>T p.Q63H | Missense Mutation (SNP) | VAF 74/535 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- LAMP5 | c.608T>A p.L203Q | Missense Mutation (SNP) | VAF 27/189 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- LHX4 | c.643C>A p.L215M | Missense Mutation (SNP) | VAF 86/452 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- LIM2 | c.244G>T p.G82C (on ENST00000596399 / NM_001161748.2; = p.G124C on NM_030657.4) | Missense Mutation (SNP) | VAF 129/597 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LIM2 | c.243G>T p.M81I (on ENST00000596399 / NM_001161748.2; = p.M123I on NM_030657.4) | Missense Mutation (SNP) | VAF 130/594 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- LIMS1 | c.580G>T p.G194C | Missense Mutation (SNP) | VAF 40/331 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- LPIN3 | c.1574G>T p.G525V | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- LRFN2 | c.2204G>T p.G735V | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LRP1 | c.11562G>T p.M3854I | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2
- LRP2 | c.9661C>A p.L3221I | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.042); called by muse, mutect2
- LRP5 | c.3371G>T p.G1124V | Missense Mutation (SNP) | VAF 46/367 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, varscan2
- LRRC6 | c.1226+1G>C p.X409_splice | Splice Site (SNP) | VAF 18/155 reads (12%) | called by muse, mutect2, varscan2
- LUM | c.178A>T p.S60C | Missense Mutation (SNP) | VAF 35/248 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- MAP2 | c.3596G>T p.G1199V | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); called by muse, mutect2
- MAPK4 | c.1588G>T p.D530Y | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- MAPKAPK5 | c.110+1G>T p.X37_splice | Splice Site (SNP) | VAF 24/149 reads (16%) | called by muse, mutect2, varscan2
- MARCHF11 | c.999C>A p.S333R | Missense Mutation (SNP) | VAF 64/485 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- MB | c.403G>C p.A135P | Missense Mutation (SNP) | VAF 27/221 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MC3R | c.351C>G p.D117E | Missense Mutation (SNP) | VAF 32/580 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2
- MCTP1 | c.2080G>A p.D694N | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MED13 | c.3821G>T p.C1274F | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MEGF11 | c.1151G>T p.G384V | Missense Mutation (SNP) | VAF 41/270 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MGA | c.2317C>T p.P773S | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.097); called by muse, mutect2
- MME | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 33/324 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- MMRN1 | c.1055T>C p.V352A | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- MOV10L1 | c.2846G>T p.R949M | Missense Mutation (SNP) | VAF 37/226 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MRC1 | c.455G>T p.G152V | Missense Mutation (SNP) | VAF 36/327 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- MROH2A | c.1648G>A p.A550T | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- MRPL38 | c.618T>A p.Y206* | Nonsense Mutation (SNP) | VAF 56/415 reads (13%) | called by muse, mutect2, varscan2
- MRTFA | c.356G>T p.R119L | Missense Mutation (SNP) | VAF 49/320 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MS4A14 | c.1987G>T p.A663S | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, mutect2
- MTERF3 | c.487G>T p.G163C | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MTG2 | c.658G>C p.E220Q | Missense Mutation (SNP) | VAF 36/528 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MTMR6 | c.809G>T p.G270V | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- MTMR6 | c.808G>T p.G270* | Nonsense Mutation (SNP) | VAF 10/73 reads (14%) | called by muse, mutect2, varscan2
- MTPAP | c.158-2A>G p.X53_splice | Splice Site (SNP) | VAF 30/246 reads (12%) | called by muse, mutect2, varscan2
- MUC12 | c.889G>T p.A297S (on ENST00000379442; = p.A154S on NM_001164462.1) | Missense Mutation (SNP) | VAF 112/797 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- MUC12 | c.9946A>G p.T3316A (on ENST00000379442; = p.T3173A on NM_001164462.1) | Missense Mutation (SNP) | VAF 82/2218 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); called by muse, mutect2
- MUC22 | c.3665G>T p.G1222V | Missense Mutation (SNP) | VAF 84/463 reads (18%) | SIFT tolerated (0.09); called by muse, mutect2, varscan2
- MUC6 | c.256C>A p.L86M | Missense Mutation (SNP) | VAF 68/653 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); called by muse, mutect2
- MYBL2 | c.876G>T p.W292C | Missense Mutation (SNP) | VAF 60/453 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MYH1 | c.1897+1G>T p.X633_splice | Splice Site (SNP) | VAF 13/84 reads (15%) | called by muse, mutect2, varscan2
- MYH8 | c.234del p.V79Sfs*4 | Frame Shift Del (DEL) | VAF 54/356 reads (15%) | called by mutect2, pindel, varscan2
- MYO18B | c.5596A>T p.S1866C | Missense Mutation (SNP) | VAF 35/206 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- MYO1F | c.329G>A p.G110E | Missense Mutation (SNP) | VAF 35/280 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MYO7B | c.2880G>T p.E960D | Missense Mutation (SNP) | VAF 63/444 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYO7B | c.3442A>T p.M1148L | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYT1L | c.2366C>G p.T789S | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.722); called by muse, mutect2
- NAV1 | c.4796dup p.D1600Gfs*30 | Frame Shift Ins (INS) | VAF 21/198 reads (11%) | called by mutect2, pindel, varscan2
- NAV2 | c.7394G>T p.S2465I (on ENST00000396087 / NM_001244963.2; = p.S2406I on NM_145117.5) | Missense Mutation (SNP) | VAF 31/291 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NBAS | c.3203G>C p.S1068T | Missense Mutation (SNP) | VAF 24/224 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- NCKAP1 | c.806G>T p.C269F | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- NCKAP5 | c.4508G>T p.G1503V | Missense Mutation (SNP) | VAF 20/273 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); called by muse, mutect2
- NDUFA10 | c.619A>T p.I207F | Missense Mutation (SNP) | VAF 37/477 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); called by muse, mutect2
- NDUFS8 | c.272T>A p.L91Q | Missense Mutation (SNP) | VAF 27/397 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2
- NHLH2 | c.274G>T p.A92S | Missense Mutation (SNP) | VAF 44/544 reads (8%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.992); called by muse, mutect2
- NKAIN3 | c.101G>A p.W34* | Nonsense Mutation (SNP) | VAF 12/124 reads (10%) | called by muse, mutect2
- NLRC4 | c.2023C>A p.Q675K | Missense Mutation (SNP) | VAF 21/279 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2
- NLRC5 | c.2017C>T p.P673S | Missense Mutation (SNP) | VAF 34/196 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NLRP10 | c.294C>G p.Y98* | Nonsense Mutation (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2, varscan2
- NLRP12 | c.2267G>A p.S756N | Missense Mutation (SNP) | VAF 103/539 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- NLRP4 | c.2901G>T p.Q967H | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- NOP58 | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- NPAS3 | c.1873G>C p.G625R (on ENST00000356141 / NM_001164749.2; = p.G593R on NM_022123.3) | Missense Mutation (SNP) | VAF 112/545 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- NPIPB2 | c.968C>A p.P323H (on ENST00000399147; = p.P183H on NM_001355514.1) | Missense Mutation (SNP) | VAF 139/1092 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- NPR1 | c.395G>T p.W132L | Missense Mutation (SNP) | VAF 133/934 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- NR3C2 | c.2177A>T p.Q726L | Missense Mutation (SNP) | VAF 28/236 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- NR5A2 | c.1454C>G p.T485R (on ENST00000367362 / NM_205860.3; = p.T439R on NM_003822.5) | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- NRCAM | c.2631C>A p.H877Q (on ENST00000379028 / NM_001371124.1; = p.H861Q on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/277 reads (21%) | SIFT tolerated (0.91); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- NSD3 | c.1921G>A p.E641K | Missense Mutation (SNP) | VAF 19/168 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- NUAK1 | c.1386G>A p.M462I | Missense Mutation (SNP) | VAF 69/392 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- NUMBL | c.482G>T p.C161F | Missense Mutation (SNP) | VAF 89/390 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- NXPH1 | c.202A>T p.N68Y | Missense Mutation (SNP) | VAF 51/291 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- OR10H1 | c.118C>A p.L40M | Missense Mutation (SNP) | VAF 49/263 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR1E1 | c.101T>C p.M34T | Missense Mutation (SNP) | VAF 42/299 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- OR1J1 | c.531C>A p.Y177* | Nonsense Mutation (SNP) | VAF 53/370 reads (14%) | called by muse, mutect2, varscan2
- OR2AJ1 | c.470C>G p.T157R | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- OR2T2 | c.49G>T p.G17C | Missense Mutation (SNP) | VAF 94/1468 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- OR4A16 | c.459C>A p.H153Q | Missense Mutation (SNP) | VAF 45/362 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR4K14 | c.233C>A p.A78D | Missense Mutation (SNP) | VAF 49/202 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- OR52A1 | c.556G>T p.A186S | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- OR52A1 | c.555G>T p.M185I | Missense Mutation (SNP) | VAF 10/227 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.562); called by muse, mutect2
- OR52B2 | c.461G>A p.S154N | Missense Mutation (SNP) | VAF 37/344 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- OR5I1 | c.296G>T p.C99F | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- OR5L1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OR5L1 | c.4G>T p.G2C | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- OR8G5 | c.575C>T p.T192I | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- OTUD1 | c.281G>T p.G94V | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- OVCH1 | c.1250C>A p.S417* | Nonsense Mutation (SNP) | VAF 8/60 reads (13%) | called by muse, mutect2, varscan2
- OVGP1 | c.1234G>T p.A412S | Missense Mutation (SNP) | VAF 19/229 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.095); called by muse, mutect2
- PACS1 | c.2561G>C p.R854P | Missense Mutation (SNP) | VAF 37/367 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PAK1 | c.900G>T p.Q300H | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- PAQR4 | c.602G>A p.G201D | Missense Mutation (SNP) | VAF 26/214 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PASD1 | c.2218C>G p.Q740E | Missense Mutation (SNP) | VAF 70/189 reads (37%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCBP3 | c.857-1G>T p.X286_splice | Splice Site (SNP) | VAF 10/240 reads (4%) | called by muse, mutect2
- PCDH18 | c.1868G>C p.G623A | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); called by muse, mutect2
- PCDHA12 | c.616C>G p.P206A | Missense Mutation (SNP) | VAF 24/266 reads (9%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.03); called by muse, mutect2
- PCDHA6 | c.550A>G p.I184V | Missense Mutation (SNP) | VAF 30/203 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PCDHB5 | c.437C>G p.T146S | Missense Mutation (SNP) | VAF 59/202 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PCLO | c.11836C>A p.P3946T | Missense Mutation (SNP) | VAF 67/326 reads (21%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- PCNX3 | c.5476G>T p.G1826C | Missense Mutation (SNP) | VAF 50/433 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- PEG3 | c.4321G>T p.G1441* | Nonsense Mutation (SNP) | VAF 90/444 reads (20%) | called by muse, mutect2, varscan2
- PEG3 | c.3771G>C p.Q1257H | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- PGAP2 | c.208G>A p.E70K (on ENST00000463452 / NM_001346398.2; = p.E131K on NM_014489.4) | Missense Mutation (SNP) | VAF 37/385 reads (10%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.625); called by muse, mutect2
- PGBD1 | c.123G>T p.E41D | Missense Mutation (SNP) | VAF 52/318 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- PHF19 | c.1400+1G>T p.X467_splice | Splice Site (SNP) | VAF 22/283 reads (8%) | called by muse, mutect2
- PHTF2 | c.1426G>T p.D476Y (on ENST00000248550 / NM_001366089.1; = p.D438Y on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- PIANP | c.122C>A p.A41D | Missense Mutation (SNP) | VAF 97/305 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- PIAS2 | c.1165G>T p.D389Y | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PIGK | c.652C>G p.P218A | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); called by muse, mutect2
- PITRM1 | c.1742G>C p.G581A | Missense Mutation (SNP) | VAF 13/266 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.874); called by muse, mutect2
- PKD1 | c.2161G>C p.A721P | Missense Mutation (SNP) | VAF 66/551 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PKHD1L1 | c.3376G>T p.A1126S | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.097); called by muse, mutect2
- PKN3 | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 17/242 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2
- PLA1A | c.772dup p.C258Lfs*2 | Frame Shift Ins (INS) | VAF 19/143 reads (13%) | called by mutect2, pindel, varscan2
- PLB1 | c.308G>A p.C103Y | Missense Mutation (SNP) | VAF 49/266 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- PODN | c.1337A>G p.E446G (on ENST00000395871; = p.E398G on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/366 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2
- POLQ | c.4243C>T p.P1415S | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2
- POTEH | c.84C>A p.C28* | Nonsense Mutation (SNP) | VAF 205/934 reads (22%) | called by muse, mutect2, varscan2
- PPHLN1 | c.300G>T p.R100S | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- PPP1R32 | c.1271A>T p.H424L | Missense Mutation (SNP) | VAF 33/411 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.048); called by muse, mutect2
- PRAMEF11 | c.1223A>T p.K408I | Missense Mutation (SNP) | VAF 61/1020 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.311); called by muse, mutect2
- PRDM5 | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 9/202 reads (4%) | called by muse, mutect2
- PREX1 | c.3460G>T p.E1154* | Nonsense Mutation (SNP) | VAF 28/540 reads (5%) | called by muse, mutect2
- PSG6 | c.1301T>A p.L434Q | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- PSG7 | c.89C>A p.P30Q | Missense Mutation (SNP) | VAF 52/142 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- PSPC1 | c.1445G>C p.R482T | Missense Mutation (SNP) | VAF 35/342 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.879); called by muse, mutect2
- PTPN21 | c.872A>T p.K291I | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPN5 | c.1082G>T p.G361V | Missense Mutation (SNP) | VAF 15/155 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- PTPRQ | c.2664T>A p.S888R (on ENST00000616559; = p.S846R on NM_001145026.2) | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PTPRQ | c.5476C>A p.P1826T (on ENST00000616559; = p.P1784T on NM_001145026.2) | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- R3HDM1 | c.2777G>T p.G926V | Missense Mutation (SNP) | VAF 26/208 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RAI14 | c.140C>G p.T47S | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- RAPGEF2 | c.211G>T p.G71C | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); called by muse, mutect2
- RAX | c.784G>T p.G262C | Missense Mutation (SNP) | VAF 53/328 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RB1 | c.888dup p.I297Yfs*13 | Frame Shift Ins (INS) | VAF 6/56 reads (11%) | called by mutect2, pindel
- RDH10 | c.973A>G p.I325V | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0.037); called by muse, mutect2
- RELN | c.4640G>T p.R1547L | Missense Mutation (SNP) | VAF 52/221 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- RELN | c.2197G>C p.E733Q | Missense Mutation (SNP) | VAF 168/778 reads (22%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- RELN | c.1269_1274del p.F424_E425del | In Frame Del (DEL) | VAF 71/453 reads (16%) | called by mutect2, pindel, varscan2
- RELN | c.478A>C p.T160P | Missense Mutation (SNP) | VAF 32/291 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RFTN2 | c.549G>A p.M183I | Missense Mutation (SNP) | VAF 40/295 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RGPD4 | c.1666G>T p.V556F | Missense Mutation (SNP) | VAF 46/298 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, varscan2
- RGS14 | c.877G>T p.E293* | Nonsense Mutation (SNP) | VAF 55/389 reads (14%) | called by muse, mutect2, varscan2
- RGS5 | c.23A>C p.Q8P | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2
- RIDA | c.187G>T p.G63C | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- RNF213 | c.3133G>T p.D1045Y | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- ROBO2 | c.2374G>T p.V792L | Missense Mutation (SNP) | VAF 10/147 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- RPAIN | c.532G>T p.G178C | Missense Mutation (SNP) | VAF 79/378 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- RPL35 | c.115G>C p.G39R | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- RPL3L | c.758G>C p.C253S | Missense Mutation (SNP) | VAF 64/380 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RRS1 | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.425); called by muse, mutect2
- RYR1 | c.5596A>T p.I1866F | Missense Mutation (SNP) | VAF 105/382 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- RYR1 | c.6670C>A p.R2224S | Missense Mutation (SNP) | VAF 137/669 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- RYR2 | c.820C>A p.L274I | Missense Mutation (SNP) | VAF 22/221 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- RYR2 | c.1036G>C p.V346L | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- RYR2 | c.13392G>T p.Q4464H | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- SACS | c.13164G>C p.Q4388H | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- SBK1 | c.275A>G p.K92R | Missense Mutation (SNP) | VAF 65/423 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- SCN3A | c.1592G>A p.S531N | Missense Mutation (SNP) | VAF 39/259 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- SCUBE1 | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 45/338 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SDHA | c.8G>T p.G3V | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2
- SERINC2 | c.391G>C p.G131R (on ENST00000373709 / NM_178865.5; = p.G135R on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); called by muse, mutect2
- SERPINA5 | c.1057G>T p.V353L | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SERPINE1 | c.116G>T p.G39V | Missense Mutation (SNP) | VAF 117/488 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SETD1B | c.2446C>T p.P816S | Missense Mutation (SNP) | VAF 44/274 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- SEZ6L | c.385A>G p.R129G | Missense Mutation (SNP) | VAF 28/440 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); called by muse, mutect2
- SFSWAP | c.2321A>T p.Y774F | Missense Mutation (SNP) | VAF 48/294 reads (16%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- SHISA2 | c.660G>T p.M220I | Missense Mutation (SNP) | VAF 80/398 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SIGLEC12 | c.557T>A p.V186D (on ENST00000291707 / NM_053003.4; = p.V68D on NM_033329.2) | Missense Mutation (SNP) | VAF 40/578 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); called by muse, mutect2
- SIRPA | c.972G>T p.R324S | Missense Mutation (SNP) | VAF 76/538 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); called by muse, varscan2
- SKAP2 | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- SLC12A7 | c.2656G>T p.D886Y | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- SLC15A1 | c.137G>T p.S46I | Missense Mutation (SNP) | VAF 15/196 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.025); called by muse, mutect2
- SLC15A3 | c.109G>T p.A37S | Missense Mutation (SNP) | VAF 24/222 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- SLC22A12 | c.1535C>A p.A512E | Missense Mutation (SNP) | VAF 160/1050 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- SLC38A3 | c.1203G>T p.E401D | Missense Mutation (SNP) | VAF 9/160 reads (6%) | SIFT tolerated (0.89); PolyPhen benign (0.012); called by muse, mutect2
- SLC39A12 | c.191T>C p.L64P | Missense Mutation (SNP) | VAF 28/506 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- SLC46A1 | c.544G>T p.A182S | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- SLC5A7 | c.778A>T p.R260W | Missense Mutation (SNP) | VAF 39/256 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC6A5 | c.722G>C p.G241A | Missense Mutation (SNP) | VAF 58/631 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC8A1 | c.2104G>T p.G702W | Missense Mutation (SNP) | VAF 41/352 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLITRK2 | c.98G>T p.C33F | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SMOC2 | c.826T>G p.Y276D (on ENST00000356284 / NM_001166412.2; = p.Y287D on NM_022138.3) | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); called by muse, mutect2
- SND1 | c.2306G>C p.R769T | Missense Mutation (SNP) | VAF 64/692 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); called by muse, mutect2
- SOX3 | c.878C>A p.P293Q | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- SPATA31A6 | c.3251C>A p.P1084H | Missense Mutation (SNP) | VAF 184/1350 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- SPATA31D1 | c.2800G>T p.D934Y | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- SPATA31E1 | c.781T>A p.S261T | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.142); called by muse, mutect2
- SPATA48 | c.183C>A p.N61K | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.385); called by muse, mutect2, varscan2
- SPATA6L | c.177+1G>T p.X59_splice | Splice Site (SNP) | VAF 16/110 reads (15%) | called by muse, mutect2, varscan2
- SPATC1 | c.289C>A p.L97M | Missense Mutation (SNP) | VAF 34/412 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.358); called by muse, mutect2
- SPEF2 | c.899A>G p.D300G | Missense Mutation (SNP) | VAF 38/213 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SPIC | c.586G>T p.A196S | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- SPOUT1 | c.758G>T p.R253L | Missense Mutation (SNP) | VAF 54/434 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- SPSB1 | c.303G>T p.Q101H | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); called by muse, mutect2
- SPTBN4 | c.606C>G p.I202M | Missense Mutation (SNP) | VAF 22/352 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); called by muse, mutect2
- SRRM3 | c.1393G>T p.A465S | Missense Mutation (SNP) | VAF 37/243 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- SSH1 | c.2532G>T p.R844S | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.169); called by muse, mutect2
- ST18 | c.3044C>T p.T1015I | Missense Mutation (SNP) | VAF 13/179 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- STK31 | c.1381G>T p.E461* | Nonsense Mutation (SNP) | VAF 18/144 reads (13%) | called by muse, mutect2, varscan2
- STRA6 | c.1301G>T p.G434V | Missense Mutation (SNP) | VAF 38/260 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STYXL2 | c.2213A>G p.K738R | Missense Mutation (SNP) | VAF 58/306 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SUGCT | c.427C>A p.L143M | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.968); called by muse, mutect2
- SYNPO2 | c.2056G>T p.E686* | Nonsense Mutation (SNP) | VAF 29/352 reads (8%) | called by muse, mutect2
- SYT4 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 69/426 reads (16%) | SIFT tolerated (0.83); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TARS1 | c.499A>T p.R167* | Nonsense Mutation (SNP) | VAF 20/245 reads (8%) | called by muse, mutect2
- TAS2R39 | c.453G>T p.R151S | Missense Mutation (SNP) | VAF 88/374 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- TBC1D5 | c.979C>T p.P327S | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- TBX18 | c.762C>A p.D254E | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.675); called by muse, mutect2
- TECTA | c.5846G>A p.G1949D | Missense Mutation (SNP) | VAF 98/528 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- THSD1 | c.1805G>T p.R602M | Missense Mutation (SNP) | VAF 33/392 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); called by muse, mutect2
- TLL1 | c.2270G>C p.R757P | Missense Mutation (SNP) | VAF 43/361 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TLR3 | c.1458G>A p.M486I | Missense Mutation (SNP) | VAF 32/203 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- TLR4 | c.1398C>G p.I466M (on ENST00000355622 / NM_138554.5; = p.I426M on NM_003266.4) | Missense Mutation (SNP) | VAF 7/155 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); called by muse, mutect2
- TLR4 | c.1992C>A p.C664* (on ENST00000355622 / NM_138554.5; = p.C624* on NM_003266.4) | Nonsense Mutation (SNP) | VAF 8/132 reads (6%) | called by muse, mutect2
- TMC1 | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 34/252 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TMED5 | c.103G>T p.D35Y | Missense Mutation (SNP) | VAF 58/287 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TMEM65 | c.274C>A p.H92N | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.307); called by muse, mutect2
- TMEM86B | c.551G>T p.G184V | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- TMPRSS7 | c.1081C>G p.P361A (on ENST00000452346; = p.P235A on NM_001042575.2) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by mutect2, varscan2
- TPO | c.94+1G>T p.X32_splice | Splice Site (SNP) | VAF 26/358 reads (7%) | called by muse, mutect2
- TRAV25 | c.269G>T p.S90I | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); called by muse, varscan2
- TRBV24-1 | c.121G>T p.E41* | Nonsense Mutation (SNP) | VAF 79/334 reads (24%) | called by muse, mutect2, varscan2
- TRIM24 | c.2152G>T p.E718* (on ENST00000343526 / NM_015905.3; = p.E684* on NM_003852.4) | Nonsense Mutation (SNP) | VAF 22/140 reads (16%) | called by muse, mutect2, varscan2
- TRIM41 | c.1547G>T p.G516V | Missense Mutation (SNP) | VAF 43/296 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- TRIM64B | c.1180C>A p.P394T | Missense Mutation (SNP) | VAF 54/642 reads (8%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.777); called by muse, mutect2
- TRIO | c.8129G>T p.G2710V | Missense Mutation (SNP) | VAF 48/543 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRIOBP | c.6937-2A>T p.X2313_splice (on ENST00000644935 / NM_001039141.3; = p.X600_splice on NM_007032.5) | Splice Site (SNP) | VAF 68/517 reads (13%) | called by muse, mutect2, varscan2
- TRPC4 | c.1706A>T p.Q569L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- TRPC6 | c.385G>T p.V129L | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRPM5 | c.1468C>A p.R490S | Missense Mutation (SNP) | VAF 19/200 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.047); called by muse, mutect2
- TTBK2 | c.2873C>T p.S958L | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2
- TTC14 | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.895); called by muse, mutect2
- TTC21B | c.2804A>T p.D935V | Missense Mutation (SNP) | VAF 42/600 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.093); called by muse, mutect2
- TTLL7 | c.1220A>G p.K407R | Missense Mutation (SNP) | VAF 46/240 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TTN | c.53039T>A p.L17680Q (on ENST00000591111; = p.L10256Q on NM_003319.4) | Missense Mutation (SNP) | VAF 6/110 reads (5%) | PolyPhen probably damaging (0.999); called by muse, mutect2
- TTN | c.2156A>T p.E719V (on ENST00000591111; = p.E673V on NM_003319.4) | Missense Mutation (SNP) | VAF 29/293 reads (10%) | PolyPhen possibly damaging (0.663); called by muse, mutect2
- TUBA3D | c.787C>A p.P263T | Missense Mutation (SNP) | VAF 66/387 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- UACA | c.2464G>T p.E822* | Nonsense Mutation (SNP) | VAF 16/71 reads (23%) | called by muse, mutect2, varscan2
- UBA6 | c.1328A>G p.Y443C | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- UBQLN3 | c.1460G>A p.R487K | Missense Mutation (SNP) | VAF 13/229 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.033); called by muse, mutect2
- UGT2B4 | c.1379C>G p.A460G | Missense Mutation (SNP) | VAF 22/378 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- UGT8 | c.426G>T p.M142I | Missense Mutation (SNP) | VAF 47/346 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- UNC5D | c.514A>T p.I172F | Missense Mutation (SNP) | VAF 34/296 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- UNC79 | c.7631C>A p.A2544E (on ENST00000393151 / NM_001346218.2; = p.A2367E on NM_020818.5) | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); called by muse, varscan2
- UNC80 | c.1846G>T p.A616S | Missense Mutation (SNP) | VAF 72/503 reads (14%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- USF2 | c.263A>T p.Q88L | Missense Mutation (SNP) | VAF 40/181 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- USH2A | c.8948T>A p.V2983D | Missense Mutation (SNP) | VAF 23/453 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2
- VAV1 | c.2211dup p.L738Afs*32 | Frame Shift Ins (INS) | VAF 29/145 reads (20%) | called by mutect2, pindel, varscan2
- VIM | c.625-2A>T p.X209_splice | Splice Site (SNP) | VAF 37/379 reads (10%) | called by muse, mutect2, varscan2
- VNN3 | c.379T>C p.C127R | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WASF2 | c.775T>G p.S259A | Missense Mutation (SNP) | VAF 53/374 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- WASHC2C | c.264G>C p.M88I | Missense Mutation (SNP) | VAF 23/206 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- WASHC5 | c.2495C>T p.T832I | Missense Mutation (SNP) | VAF 19/349 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- WDR64 | c.2494G>T p.A832S | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- WDR87 | c.5101C>A p.P1701T | Missense Mutation (SNP) | VAF 58/283 reads (20%) | SIFT tolerated (0.95); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WDR93 | c.166C>A p.P56T | Missense Mutation (SNP) | VAF 53/376 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- WWC2 | c.841A>T p.T281S | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- XPNPEP1 | c.299A>T p.D100V | Missense Mutation (SNP) | VAF 36/297 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- ZBBX | c.740T>A p.L247Q | Missense Mutation (SNP) | VAF 25/174 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- ZDHHC11 | c.744G>T p.L248F | Missense Mutation (SNP) | VAF 34/1061 reads (3%) | SIFT tolerated (0.28); PolyPhen benign (0.147); called by muse, mutect2
- ZFHX3 | c.3892A>T p.S1298C | Missense Mutation (SNP) | VAF 64/337 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- ZFHX4 | c.8089C>T p.R2697W | Missense Mutation (SNP) | VAF 20/289 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
398 further variants in this file (20 protein-altering or splice-affecting, 241 silent, 137 other) are not listed here.
